Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A49I, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A49I-01A (Primary Tumor).

[page 1 of 6]
Referring Physician: _____

DOB: _____ Age: _____ Gender: M

Ref#: _____ Hosp#: _____ Provider Group: _____

Date of Service: _____ Date Received: _____ Inpatient Case #: _____
Room: _____ Bed _____ Date Reported: _____

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. PANCREAS WITH DISTAL STOMACH, DUODENUM AND GALLBLADDER, WHIPPLE PROCEDURE WITH TOTAL PANCREATECTOMY AND CHOLECYSTECTOMY:

- INFILTRATIVE DUCTAL CARCINOMA, MODERATELY DIFFERENTIATED WITH
LOW-GRADE NEUROENDOCRINE COMPONENT. *Not measurable per TSS 9/4/12*
- Tumor size 5.0 cm involving head of pancreas. *fw*
- Positive for extra-pancreatic extension.
- MARGINS: TUMOR INVOLVES THE PANCREATIC NOTCH MARGIN.
- THREE OF SEVEN PERIPANCREATIC LYMPH NODES POSITIVE FOR
MALIGNANCY (3/7).
- HIGH GRADE, PANCREATIC INTRAEPITHELIAL NEOPLASIA (PanIn III).

B. PORTAL LYMPH NODES, EXCISION:

- TWO BENIGN LYMPH NODES (0/2).

PATHOLOGIC TUMOR STAGING SUMMARY:

Histologic type and grade: Infiltrative ductal carcinoma, moderately differentiated
with low-grade neuroendocrine component.

Primary tumor: pT3.

Regional lymph nodes: pN1 (3/9). [Specimen A and B]

Distant metastasis: Not applicable.

Margin status: R1, pancreatic notch positive.

Pathologic stage: IIB.

Lymphovascular invasion: Positive.

Perineural invasion: Not identified.

1CD-0-3

adenocarcinoma, duct, NOS 8500/3

Site: pancreas, head c 25.0

fw 9/27/12

COMMENT: The tumor is a ductal adenocarcinoma with a low-grade neuroendocrine component (mixed ductal-endocrine carcinoma). The lymphovascular invasion, positive lymph nodes and positive margin are all associated with the ductal adenocarcinoma. These neoplasms behave according to the ductal adenocarcinoma component.

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 6]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

The preliminary findings were discussed with
case was shown in intradepartmental consultation with

.. This

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol,

Case #:

Printed:

Page 2

This report continues... (FINAL)

[page 3 of 6]
Case #:

Specimen:	Pancreas with distal stomach, duodenum and gallbladder.
Procedure:	Whipple procedure (total pancreatectomy) and cholecystectomy.
TUMOR FEATURES:	
Tumor site:	Head of pancreas.
Tumor size:	5.0 x 4.5 x 3.3 cm.
Histologic type:	Infiltrative ductal carcinoma with neuroendocrine component.
Histologic grade:	Grade 2, moderately differentiated.
Microscopic tumor extension:	Tumor extends into extra-pancreatic adipose tissue.
Margins:	POSITIVE pancreatic notch margin; Tumor 2.0 mm from posterior margin. Stomach, duodenum and common bile duct margin negative.
Treatment effect:	Not applicable.
Lymphovascular invasion:	Positive.
Perineural invasion:	Not identified.
Lymph nodes:	Three of nine peripancreatic and portal lymph nodes positive for malignancy (3/9). [Specimen A and B]
Pathologic tumor staging:	
Primary tumor:	pT3.
Regional lymph nodes:	pN1.
Distant metastasis:	Not applicable.
Pathologic stage:	IIB.
Additional findings:	- High-grade pancreatic intraepithelial neoplasia (PanIn III).- Chronic pancreatitis.- Mesothelial cysts.- Gallbladder with mild chronic cholecystitis, cholesterosis and cholelithiasis.

Case #:

Printed:

Page 3

This report continues... (FINAL)

[page 4 of 6]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Total Pancreatectomy
- B. Lymph node; Portal lymph node

Clinical History/Operative Dx:

Pancreatic tumor

Intraoperative Diagnosis:

- A. Whipple, total pancreatectomy: Bile duct margin free of tumor The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled gallbladder, total pancreatectomy and is received without fixative. It consists of a composite resection which consists of a wedge of gastric tissue measuring 9 x 6.5 x 2.5 cm and a 30 cm segment of duodenum. Attached to the duodenum is a total pancreatectomy specimen with a palpable mass at the head of the pancreas. The pancreas overall is 19 cm in length, 6.5 cm from superior to inferior and approximately 4.8 cm from anterior to posterior. Blue ink is applied to the superior edge of the pancreas, orange ink to the posterior lateral surface, red ink is applied to the pancreatic notch, and black ink is applied to the posterior/uncinate portion of the pancreas. Green ink is applied along the anterior surface. The free serosal surface of the gastric resection and the duodenum is pale red and smooth.

The specimen is opened to reveal darkly hemorrhagic gastric mucosa with a rugose pattern extending to the pylorus. The pylorus has a prominent appearance but there is no ulceration or abnormality at the pylorus. 7 cm distal to the pylorus, the ampulla is identified and a probe is extended through the ampulla to located the common bile duct. The surgical margin of the common bile duct is removed and submitted for frozen section as FS1. Serial sections of the head of the pancreas reveal a gritty, tan-white, relatively well-circumscribed neoplasm which measures 5 cm from medial to lateral, 4.5 cm from superior to inferior, and 3.3 cm from anterior to posterior.

It is 9 cm from the proximal gastric margin and 14 cm from the distal duodenal margin. It is 1.3 cm from the ampulla, 0.2 cm from the closest anterior margin, 1.5 cm from the superior margin, and very close proximity to the pancreatic notch margin (inked red) and within 0.2 cm of the closest posterior/uncinate

Page 4

Case #:

Printed

This report continues... (FINAL)

[page 5 of 6]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

margin. In the superior peripancreatic tissue just adjacent to the bile duct, there is a fluid-filled, thin-walled 0.7 cm cyst. Sectioning of the remainder of the pancreas reveals fibrotic yellow-tan to tan-white parenchyma with scattered fluid-filled cysts which are up to 0.7 cm. The duodenum is up to 5.5 cm maximally. The distal 8 cm of the duodenum has dark red hemorrhagic mucosa. There are no mucosal polyps identified. The perigastric adipose tissue and peripancreatic tissue are dissected for possible nodes.

Also in the specimen container is an intact gallbladder which is 7.7 cm in length and 3.8 cm in diameter. The serosal surface is pale violet and smooth. The cystic duct is narrow but patent. The gallbladder wall is up to 0.3 cm in thickness. The mucosa is yellow and velvety with spotty yellow mucosal stippling. There is a single 0.3 cm black calculus. Representative sections are submitted

Section summary:

- A1) bile duct margin from frozen section,
- A2) representative proximal gastric margin,
- A3) representative distal gastric tissue,
- A4) pylorus,
- A5) ampulla with closest approach of tumor,
- A6) medial inferior pancreas,
- A7) medial and inferior pancreas and pancreatic tumor,
- A8-A9) medial superior sections of pancreas,
- A10) medial anterior surface with closest approach of tumor,
- A11-A12) pancreatic notch with closest approach of tumor,
- A13-A14) posterior and uncinate surface of pancreas with closest approach of tumor,
- A15) superior edge of pancreas along lateral edge of tumor,
- A16) lateral tumor and pancreatic notch,
- A17-A20) sections of pancreas from mid pancreas to pancreatic tail,
- A21) section of lateral most portion of pancreatic tail,
- A22) distal duodenal margin,
- A23) gallbladder,
- A24) two possible peripancreatic nodes,
- A25) possible perigastric and periduodenal nodes.

B. The specimen is labeled portal lymph node and is received in formalin. It consists of a 2.5 x 1.8 x 1.3 cm fragment of lobulated fatty tissue. On dissection two possible nodes are recovered ranging from 1.4 - 1 cm. The larger possible node is serially sectioned and is submitted in cassette B1, the smaller node is serially sectioned and submitted in cassette B2.

Microscopic Description:

A. Sections of the Whipple procedure show an invasive, moderately differentiated adenocarcinoma. The tumor forms irregular angulated and abortive glands with nuclear enlargement, marked nuclear size variability and prominent nucleoli. The tumor focally extends into the peripancreatic adipose tissue and is present at the cauterized pancreatic notch margin. The tumor is 2.0 mm from the posterior margin and all remaining margins are uninvolved. A focus of lymphovascular invasion is present but no diagnostic

Case #:

Page 5

Printed:

This report continues... (FINAL)

[page 6 of 6]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

perineural invasion is identified. Associated with the tumor is a low grade neuroendocrine component composed of large nests, cords and single file cells with round nuclei and speckled chromatin. This component is confined within the pancreas and no increased mitotic activity is present.

Immunohistochemistry for neuroendocrine markers CD56, chromogranin and synaptophysin performed on block A10 highlights the neuroendocrine component. The neuroendocrine component and ductal adenocarcinoma are both highlighted by immunohistochemistry for cytokeratin 7.

A total of seven lymph nodes are identified, of which three are positive for malignancy. One lymph node metastasis is highlighted by immunohistochemistry for OSCAR-cytokeratin (block A8).

Additional findings include extensive chronic pancreatitis with variable ductal dilatation and intraepithelial neoplasia which ranges from low-grade to high grade (PanIN III). Adjacent benign mesothelial cysts are present. There is mild gastritis but the stomach is otherwise unremarkable. The gallbladder has mild chronic cholecystitis with foamy histiocytes in the mucosa. Within the pancreas, there is a focus with dense eosinophilic change. Congo red special stain for amyloid is negative.

B. The sections of the portal lymph node specimen show two benign lymph nodes (0/2). No malignancy is identified.

Reviewed/Initials	Date Reviewed: 8/20/12	

9/4/12

Page 6

END OF REPORT (FINAL)

Case #:

Printed:

Source: NCI Genomic Data Commons file 57db7582-0829-46a5-a121-90add8619ec3 (TCGA-HZ-A49I.8A955296-DAF7-48EE-8368-CEC37A796D1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).